Somatic mutation profile of tumor specimen TARGET-20-PASTPU-09A (aliquot TARGET-20-PASTPU-09A-02D) from TARGET case TARGET-20-PASTPU, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.2 years (5,917 days).
Specimen TARGET-20-PASTPU-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26426541-81cc-42ef-9882-a0bfcb6ea877.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASTPU-14A (Bone Marrow Normal), aliquot TARGET-20-PASTPU-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8d384315-7812-465e-868c-ec002c4a9570

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Silent 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEBPA | c.912_913insGC p.Q305Afs*14 | Frame Shift Ins (INS) | VAF 46/83 reads (55%) | catalogued as COSV57196793, COSV57196937, COSV57200730; called by mutect2, varscan2*
- RAD21 | c.1645C>T p.Q549* | Nonsense Mutation (SNP) | VAF 52/137 reads (38%) | catalogued as COSV52056346; called by muse, mutect2, varscan2
- GJA1 | c.1057T>C p.L353= | Silent (SNP) | VAF 8/183 reads (4%) | called by muse, mutect2
